Somatic mutation profile of tumor specimen SM-JU335 (aliquot 7316UP-1843) from CPTAC case C760878, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Frontal lobe; Tumor grade: G3.
Specimen SM-JU335: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e5fe7f6-294b-4822-acc4-991fbd6a0c09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105278 (Blood Derived Normal), aliquot 7316UP-1843-1105278; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dd974b4-1fde-42df-8515-18856d358743

The open-access MAF lists 85 somatic variants for this specimen: 56 protein-altering or splice-affecting, 21 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 21, Intron 7, Nonsense Mutation 4, Splice Site 4, 5'UTR 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 4357/5093 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AFF1 | c.1236_1239del p.H412Qfs*86 | Frame Shift Del (DEL) | VAF 28/157 reads (18%) | catalogued as rs765113099; called by pindel, varscan2
- BIRC6 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); catalogued as rs373105075; called by muse, mutect2, varscan2
- C3 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 148/706 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765821415, COSV55568720; called by muse, mutect2, varscan2
- CFAP20DC | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 42/130 reads (32%) | catalogued as rs952156491; called by mutect2, varscan2
- CIITA | c.3311C>T p.T1104M | Missense Mutation (SNP) | VAF 134/448 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs367805896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP4A22 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 39/166 reads (23%) | catalogued as rs1182232056, COSV53738126; called by muse, mutect2, varscan2
- EDDM3A | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 71/188 reads (38%) | catalogued as rs768794732, COSV58795108, COSV58795417; called by muse, mutect2, varscan2
- FAM53A | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as rs559109336, COSV57401825; called by muse, mutect2, varscan2
- FRAS1 | c.4814C>T p.A1605V | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs749776166; called by muse, mutect2, varscan2
- GABRA6 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 179/563 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751098162, COSV50883531; called by muse, mutect2, varscan2
- GBP3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 68/245 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs145016759; called by muse, mutect2, varscan2
- HIRA | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs376487965; called by muse, mutect2, varscan2
- HYDIN | c.10129C>T p.R3377C | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs779031423, COSV101151299, COSV101157939; called by muse, mutect2, varscan2
- KRTAP13-1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 15/327 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs374257240, COSV62664445; called by muse, mutect2
- N4BP2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs780476202, COSV54699826; called by muse, mutect2, varscan2
- NLRP4 | c.554C>G p.T185R | Missense Mutation (SNP) | VAF 82/378 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV56713550; called by muse, mutect2, varscan2
- OR4A15 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs374555766, COSV59036488; called by muse, mutect2, varscan2
- PCDH11Y | c.208G>A p.V70I (on ENST00000400457 / NM_032973.2; = p.V59I on NM_032971.3) | Missense Mutation (SNP) | VAF 210/292 reads (72%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV53082348; called by muse, mutect2, varscan2
- PROKR1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs149410240; called by muse, mutect2, varscan2
- SLC25A21 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 32/110 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs758995590; called by muse, mutect2, varscan2
- SLC6A17 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58991663; called by muse, mutect2, varscan2
- SNX13 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 74/347 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1212626732; called by muse, mutect2, varscan2
- SPOCK3 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 82/263 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446612, COSV100692812; called by muse, mutect2, varscan2
- SYT6 | c.746G>A p.R249H (on ENST00000610222 / NM_001366225.1; = p.R164H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 177/529 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs139165674, COSV101059648; called by muse, mutect2, varscan2
- TLR2 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 37/139 reads (27%) | catalogued as rs989773958, COSV52607172; called by muse, mutect2, varscan2
- TRPC6 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437212772; called by muse, mutect2, varscan2
- ZNF407 | c.5666C>T p.T1889M | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs553117551, COSV55254908; called by muse, mutect2, varscan2
- AKAP13 | c.4582G>C p.A1528P | Missense Mutation (SNP) | VAF 94/255 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- ALPP | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO3 | c.2764-1G>A p.X922_splice | Splice Site (SNP) | VAF 92/282 reads (33%) | called by muse, mutect2, varscan2
- ATP1B1 | c.101A>T p.K34M | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRIP1 | c.3398C>A p.T1133K | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- HAUS2 | c.94-2A>G p.X32_splice | Splice Site (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2
- IGBP1P2 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IGKV1D-42 | c.185C>G p.P62R | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ITPKA | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 86/271 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- LAMA1 | c.2572T>G p.S858A | Missense Mutation (SNP) | VAF 134/380 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.185); called by muse, varscan2
- LRRC8B | c.1531A>T p.N511Y | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MLLT10 | c.603+1G>A p.X201_splice | Splice Site (SNP) | VAF 41/69 reads (59%) | called by muse, mutect2, varscan2
- MTA3 | c.1657A>G p.S553G (on ENST00000405094 / NM_001330442.2; = p.S496G on NM_001282755.1) | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- OR4F17 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 151/1276 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRKCH | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QKI | c.521_523del p.E174del | In Frame Del (DEL) | VAF 22/70 reads (31%) | called by pindel, varscan2
- QRICH2 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 107/370 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- SEC24D | c.442T>G p.S148A | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB2 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A1 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 47/108 reads (44%) | called by muse, mutect2
- TAT | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 158/478 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEP1 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TMEM165 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPST1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 88/433 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- VPS18 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- YWHAZ | c.389_390insAACGTTACTTGGC p.E131Tfs*5 | Frame Shift Ins (INS) | VAF 40/146 reads (27%) | called by mutect2, varscan2
- ZMIZ1 | c.2822C>G p.P941R | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ZNF229 | c.1598T>C p.L533P | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- AP3B1 | c.1983C>T p.T661= | Silent (SNP) | VAF 60/271 reads (22%) | called by muse, mutect2, varscan2
- CAVIN1 | c.972C>T p.H324= | Silent (SNP) | VAF 129/416 reads (31%) | catalogued as rs1421562805, COSV100824606; called by muse, mutect2, varscan2
- CBFA2T3 | c.1887C>T p.S629= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as rs750626340; called by muse, mutect2
- CYP4Z1 | c.699C>T p.N233= | Silent (SNP) | VAF 20/154 reads (13%) | catalogued as rs370015142; called by muse, mutect2, varscan2
- DPP10 | c.192G>A p.S64= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as rs201248540; called by muse, mutect2, varscan2
- FLNB | c.6114G>A p.A2038= | Silent (SNP) | VAF 124/464 reads (27%) | catalogued as rs1559730956; called by muse, mutect2, varscan2
- HMGCS2 | c.879C>T p.D293= | Silent (SNP) | VAF 101/272 reads (37%) | catalogued as rs761787433, COSV65569426; called by muse, mutect2, varscan2
- HTR1E | c.105C>G p.L35= | Silent (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- MYLK3 | c.603G>A p.A201= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs781406736; called by muse, varscan2
- OR52J3 | c.654G>A p.S218= | Silent (SNP) | VAF 56/181 reads (31%) | catalogued as rs148600962, COSV66747742; called by muse, mutect2, varscan2
- OR8A1 | c.411T>C p.S137= | Silent (SNP) | VAF 85/196 reads (43%) | catalogued as rs538622740; called by muse, mutect2, varscan2
- POTEJ | c.2622C>T p.D874= | Silent (SNP) | VAF 195/816 reads (24%) | called by muse, varscan2
- PRDM9 | c.2671A>C p.R891= | Silent (SNP) | VAF 102/334 reads (31%) | called by muse, mutect2, varscan2
- PRRC2A | c.411C>T p.S137= | Silent (SNP) | VAF 44/193 reads (23%) | catalogued as rs761009382, COSV63224694; called by muse, mutect2, varscan2
- PYGB | c.156C>T p.Y52= | Silent (SNP) | VAF 54/257 reads (21%) | catalogued as rs1485964440; called by muse, mutect2, varscan2
- SEC14L5 | c.327C>T p.N109= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as rs375401992; called by muse, mutect2, varscan2
- SERHL2 | c.12C>T p.N4= | Silent (SNP) | VAF 86/382 reads (23%) | called by muse, mutect2, varscan2
- SLCO4A1 | c.891G>A p.T297= | Silent (SNP) | VAF 71/257 reads (28%) | catalogued as rs143407772, COSV53889042; called by muse, mutect2, varscan2
- TMCC2 | c.402C>T p.Y134= | Silent (SNP) | VAF 121/336 reads (36%) | catalogued as rs77588763, COSV58005035; called by muse, mutect2, varscan2
- TMEM270 | c.678C>T p.A226= | Silent (SNP) | VAF 128/553 reads (23%) | catalogued as rs201571768; called by muse, mutect2, varscan2
- TPTE2 | c.213A>T p.V71= | Silent (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- ENY2 | c.230-678C>T | Intron (SNP) | VAF 82/235 reads (35%) | called by muse, mutect2, varscan2
- FCRL5 | c.-21C>G | 5'UTR (SNP) | VAF 106/333 reads (32%) | called by muse, mutect2, varscan2
- HTN3 | c.73-34A>C | Intron (SNP) | VAF 33/90 reads (37%) | catalogued as COSV66879574; called by muse, mutect2, varscan2
- MYO10 | c.21+19724G>A | Intron (SNP) | VAF 78/235 reads (33%) | catalogued as rs772652920, COSV72454035; called by muse, mutect2, varscan2
- SNRNP200 | c.5754+39C>G | Intron (SNP) | VAF 132/395 reads (33%) | catalogued as rs746692485; called by muse, mutect2, varscan2
- TSPEAR | c.633+33G>A | Intron (SNP) | VAF 147/415 reads (35%) | catalogued as rs777838829; called by muse, mutect2, varscan2
- TTN | c.10360+1582G>A | Intron (SNP) | VAF 41/138 reads (30%) | called by muse, mutect2, varscan2
- ZNF497 | c.-111-646C>T | Intron (SNP) | VAF 13/243 reads (5%) | catalogued as rs894474633; called by muse, mutect2
